Somatic mutation profile of tumor specimen HCM-BROD-0614-C71-01A (aliquot HCM-BROD-0614-C71-01A-11D-A82H-36) from HCMI case HCM-BROD-0614-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.3 years (23,138 days).
Specimen HCM-BROD-0614-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad314dc9-a709-4044-973d-c3b4706ceb60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0614-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0614-C71-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e458260-e54b-4910-ae76-38348a5e51c3

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Nonsense Mutation 2, 3'UTR 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.3739_3742del p.F1247Ifs*18 | Frame Shift Del (DEL) | VAF 106/314 reads (34%) | catalogued as rs1064794276; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 202/539 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376T>C p.Y126H | Missense Mutation (SNP) | VAF 322/571 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM118879, COSV52661802, COSV52809424, COSV53031989, COSV53515469; called by muse, mutect2, varscan2
- FAM155B | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 56/884 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1305219133; called by muse, mutect2
- FAM160A1 | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 171/426 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.174); catalogued as COSV70709532; called by muse, mutect2, varscan2
- HIVEP3 | c.3025C>T p.R1009C | Missense Mutation (SNP) | VAF 224/532 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746529841, COSV56010759; called by muse, mutect2, varscan2
- ING1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 337/767 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.248); catalogued as COSV58171068; called by muse, mutect2, varscan2
- LHX5 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 342/821 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1226504308; called by muse, mutect2, varscan2
- MAGEB3 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 64/469 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs140421974, COSV64397165; called by muse, mutect2, varscan2
- MROH2B | c.3904C>T p.R1302* | Nonsense Mutation (SNP) | VAF 136/404 reads (34%) | catalogued as rs1228647156, COSV68182768; called by muse, mutect2, varscan2
- MYH2 | c.4000G>A p.A1334T | Missense Mutation (SNP) | VAF 91/262 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.113); catalogued as rs779257410, COSV55449691; called by muse, mutect2, varscan2
- PDLIM5 | c.1739C>T p.S580F | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770229681, COSV58745568; called by muse, mutect2, varscan2
- SLC12A3 | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 125/326 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as rs387907472; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCB1 | c.713C>G p.S238* (on ENST00000263121; = p.S284* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 28/328 reads (9%) | catalogued as COSV54098633, COSV54102124; called by muse, mutect2
- AJAP1 | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ANO8 | c.1191C>G p.F397L | Missense Mutation (SNP) | VAF 123/325 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- CPSF7 | c.5C>T p.S2L (on ENST00000394888 / NM_001136040.4; = p.S45L on NM_024811.4) | Missense Mutation (SNP) | VAF 47/427 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- DST | c.22213G>C p.D7405H (on ENST00000361203 / NM_001374722.1; = p.D5115H on NM_015548.5) | Missense Mutation (SNP) | VAF 215/546 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EGF | c.2666T>C p.I889T | Missense Mutation (SNP) | VAF 130/311 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- MET | c.3415G>A p.V1139I | Missense Mutation (SNP) | VAF 157/622 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC16A13 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 46/668 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- UBQLN3 | c.242T>G p.V81G | Missense Mutation (SNP) | VAF 200/458 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- UROD | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 202/509 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZHX3 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 160/451 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BBX | c.2814C>T p.C938= (on ENST00000325805 / NM_001142568.3; = p.C908= on NM_020235.7) | Silent (SNP) | VAF 342/620 reads (55%) | catalogued as rs565048977, COSV57885132; called by muse, mutect2, varscan2
- GPNMB | c.525C>T p.Y175= | Silent (SNP) | VAF 48/602 reads (8%) | catalogued as rs770827735, COSV51699424; called by muse, mutect2
- GRHL3 | c.561G>A p.P187= (on ENST00000350501 / NM_198174.3; = p.P192= on NM_021180.3) | Silent (SNP) | VAF 156/389 reads (40%) | catalogued as rs780285232; called by muse, mutect2, varscan2
- GSPT2 | c.261C>T p.G87= | Silent (SNP) | VAF 626/1153 reads (54%) | called by muse, mutect2, varscan2
- MFSD6L | c.357C>T p.D119= | Silent (SNP) | VAF 224/528 reads (42%) | catalogued as COSV61000909; called by muse, mutect2, varscan2
- RUNX2 | c.1413G>A p.P471= (on ENST00000371438; = p.P449= on NM_001015051.3) | Silent (SNP) | VAF 170/455 reads (37%) | catalogued as rs114897742; called by muse, mutect2, varscan2
- THOC2 | c.672C>T p.H224= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2, varscan2
- UMPS | c.549C>G p.L183= | Silent (SNP) | VAF 328/612 reads (54%) | catalogued as rs913514809, COSV51736164; called by muse, mutect2, varscan2
- ZC4H2 | c.210C>T p.H70= | Silent (SNP) | VAF 163/413 reads (39%) | catalogued as rs376951408, COSV62004355; called by muse, mutect2, varscan2
- HEPACAM2 | c.*242C>T | 3'UTR (SNP) | VAF 95/416 reads (23%) | catalogued as rs1335424577; called by muse, mutect2, varscan2
- THOP1 | c.1908+564A>G | Intron (SNP) | VAF 244/601 reads (41%) | called by muse, mutect2, varscan2
